Somatic mutation profile of tumor specimen TCGA-TQ-A7RV-02A (aliquot TCGA-TQ-A7RV-02A-11D-A36O-08) from TCGA case TCGA-TQ-A7RV, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 27.8 years (10,167 days).
Specimen TCGA-TQ-A7RV-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4605a752-dd62-436b-81af-a7cda4d9bd05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TQ-A7RV-10A (Blood Derived Normal), aliquot TCGA-TQ-A7RV-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a963793-2370-4273-a2f6-a28380d817cf

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Splice Site 1, Frame Shift Del 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- REEP1 | c.105+1G>A p.X35_splice | Splice Site (SNP) | VAF 52/197 reads (26%) | catalogued as rs1064797257, COSV99382387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 25/56 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.2198G>T p.G733V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.07); catalogued as COSV100482182, COSV100482379; called by muse, mutect2, varscan2
- IKBKE | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.3); catalogued as rs782265530, COSV100898108; called by muse, mutect2
- LCK | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100287395; called by muse, mutect2, varscan2
- MCM10 | c.829C>G p.L277V (on ENST00000484800 / NM_182751.3; = p.L276V on NM_018518.5) | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.253); catalogued as COSV101097899; called by muse, mutect2, varscan2
- PPP1R3A | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99492191; called by muse, mutect2, varscan2
- SFTPC | c.466G>T p.V156L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV100109181; called by muse, mutect2, varscan2
- TGFBRAP1 | c.511C>G p.L171V | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.029); catalogued as COSV99304676; called by muse, mutect2, varscan2
- USP15 | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 34/286 reads (12%) | catalogued as rs1259985423, COSV99738778; called by muse, mutect2, varscan2
- ZNF276 | c.1342G>A p.A448T (on ENST00000443381 / NM_001113525.2; = p.A373T on NM_152287.4) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs576654600, COSV57067701, COSV57070084; called by muse, mutect2, varscan2
- PPP2R5D | c.788del p.H263Lfs*74 | Frame Shift Del (DEL) | VAF 16/95 reads (17%) | called by mutect2, pindel, varscan2
- CHST6 | c.657G>A p.A219= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs1420289951, COSV60000015; called by muse, mutect2, varscan2
- MAST1 | c.1287C>T p.A429= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs775469424, COSV99262238; called by muse, mutect2, varscan2
- SLC1A4 | c.1128C>T p.T376= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as rs772986775, COSV99308762, COSV99308791; ClinVar: likely benign; called by muse, mutect2, varscan2
- WDR81 | c.4020G>A p.A1340= (on ENST00000409644 / NM_001163809.2; = p.A289= on NM_152348.4) | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs377573673; called by muse, mutect2
- RNU6-1191P | chr16:81109274 T>C | 5'Flank (SNP) | VAF 4/18 reads (22%) | catalogued as rs1264708481; called by muse, mutect2, varscan2
